Somatic mutation profile of tumor specimen BA2040D (aliquot aq-BA2040D) from BEATAML1.0 case 2085, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,512 days).
Specimen BA2040D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6581a3e4-aa60-4a66-b7f7-99a47d3bec78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2462D (Solid Tissue Normal), aliquot aq-BA2462D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f86798-6b88-4f53-83e1-366b29d9e6bb

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYTIP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs538136043; called by mutect2, varscan2
- DNMT3A | c.2477A>T p.K826M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV53083630; called by mutect2, varscan2
- EVC2 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1256824226; called by muse, mutect2, varscan2
- IRS1 | c.2827A>C p.K943Q | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1430188572, COSV59333714; called by muse, mutect2
- MYO6 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs377681616; called by muse, mutect2, varscan2
- NCAPG2 | c.596del p.D199Vfs*17 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | called by mutect2, pindel, varscan2
- RADIL | c.3171C>T p.V1057= | Silent (SNP) | VAF 29/216 reads (13%) | catalogued as rs773741937, COSV68202771; called by muse, mutect2, varscan2
- TEX36 | c.435A>G p.R145= | Silent (SNP) | VAF 11/207 reads (5%) | called by muse, mutect2
- GLE1 | c.-50G>C | 5'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
